FM case AD5577 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/089955ff-5c8c-4a35-a33b-ba5881a5f735

Female, 61.9 years: Carcinoma, NOS (ICD-O-3 8010/3) of the ovary; metastasis biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
